Somatic mutation profile of tumor specimen C3N-00211-01 (aliquot CPT0090440009) from CPTAC case C3N-00211, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 40.9 years (14,952 days).
Specimen C3N-00211-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4e0105b-4c49-4b59-9e14-15552de2b484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00211-31 (Blood Derived Normal), aliquot CPT0092490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e4fe1bc-8845-4b90-9a75-4723bdf30f41

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Nonsense Mutation 2, RNA 2, Frame Shift Ins 2, Intron 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 118/436 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 97/405 reads (24%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 86/301 reads (29%) | hotspot (GDC flag); catalogued as CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; called by muse, mutect2, varscan2
- ADAM12 | c.1943A>G p.Q648R | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755582023; called by muse, mutect2
- ANKRD30B | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs755217546, COSV62817501; called by muse, mutect2, varscan2
- ATP8B4 | c.2257G>C p.D753H | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV99467449; called by muse, mutect2
- CARF | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs1192272383; called by muse, mutect2
- CCDC54 | c.513C>G p.Y171* | Nonsense Mutation (SNP) | VAF 34/340 reads (10%) | catalogued as COSV53759766; called by muse, mutect2, varscan2
- CDYL2 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73654117; called by muse, mutect2, varscan2
- CYP1B1 | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV99307586; called by muse, mutect2
- FBN1 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 68/621 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1445613212, COSV57309276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.713C>G p.T238S | Missense Mutation (SNP) | VAF 117/669 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV74205779; called by muse, mutect2, varscan2
- HEATR5B | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs375534328; called by muse, mutect2, varscan2
- PCDHB15 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99178873; called by muse, mutect2, varscan2
- PEX1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 53/421 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754529845, COSV50395596, COSV50406081; called by muse, mutect2, varscan2
- PHF20L1 | c.2654A>G p.D885G | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs750306290; called by muse, mutect2
- PXDNL | c.3863C>T p.P1288L | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs372900663, CM1410447, COSV100685821; called by muse, mutect2, varscan2
- TTBK1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs150345154; called by muse, mutect2, varscan2
- ZFHX4 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as rs1218726795, COSV50479906; called by muse, mutect2, varscan2
- AGER | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 78/447 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- BRAF | c.1624G>T p.V542L (on ENST00000288602 / NM_001374244.1; = p.V502L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CHSY3 | c.2569A>G p.T857A | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2
- GRM6 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KBTBD7 | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 46/551 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KMO | c.1081A>G p.M361V | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KMT2E | c.2576del p.N859Mfs*9 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- LRP12 | c.1916A>G p.E639G | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRP2 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 85/479 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOG | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RERE | c.4511C>G p.P1504R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TPST1 | c.846-1G>C p.X282_splice | Splice Site (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- UBA2 | c.1218dup p.S407Ifs*14 | Frame Shift Ins (INS) | VAF 16/156 reads (10%) | called by pindel, varscan2
- ZNF14 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF835 | c.1154C>T p.T385I | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- BTN3A1 | c.1206G>A p.G402= | Silent (SNP) | VAF 33/296 reads (11%) | catalogued as rs778915621; called by muse, mutect2, varscan2
- C2CD4B | c.867C>A p.L289= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- CHTF18 | c.2226C>T p.S742= | Silent (SNP) | VAF 16/245 reads (7%) | catalogued as rs147259544; called by muse, mutect2
- FAM20A | c.225G>A p.E75= | Silent (SNP) | VAF 54/464 reads (12%) | catalogued as rs764564897; called by muse, mutect2, varscan2
- GPR52 | c.444C>G p.S148= | Silent (SNP) | VAF 36/378 reads (10%) | called by muse, mutect2
- LCT | c.2022G>A p.L674= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- MED12L | c.2322G>A p.K774= | Silent (SNP) | VAF 25/378 reads (7%) | called by muse, mutect2
- PCDHA5 | c.1446C>T p.D482= | Silent (SNP) | VAF 88/760 reads (12%) | catalogued as rs1328701255, COSV65349916; called by muse, mutect2, varscan2
- PRICKLE1 | c.714C>T p.F238= | Silent (SNP) | VAF 26/457 reads (6%) | catalogued as rs368850875; called by muse, mutect2
- SEC24C | c.1854A>T p.V618= | Silent (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- TTBK1 | c.3087G>A p.P1029= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs777846920; called by muse, mutect2, varscan2
- ABCB7 | c.*1G>C | 3'UTR (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.-29C>T | 5'UTR (SNP) | VAF 89/482 reads (18%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1221T>C | RNA (SNP) | VAF 23/313 reads (7%) | called by muse, mutect2
- SNORD109A | n.45T>C | RNA (SNP) | VAF 41/230 reads (18%) | catalogued as rs775725709; called by muse, mutect2, varscan2
- SOX13 | c.419-203C>T | Intron (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- ZNF213 | chr16:3145994 G>A | 3'Flank (SNP) | VAF 20/166 reads (12%) | catalogued as rs1035010041; called by muse, mutect2, varscan2
